Somatic mutation profile of tumor specimen TCGA-2Y-A9H3-01A (aliquot TCGA-2Y-A9H3-01A-11D-A382-10) from TCGA case TCGA-2Y-A9H3, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage II; Tumor grade: G1; Age at diagnosis: 45.0 years (16,443 days).
Specimen TCGA-2Y-A9H3-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1604ad3d-b837-4d73-b360-8beec0d6a378.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-2Y-A9H3-10A (Blood Derived Normal), aliquot TCGA-2Y-A9H3-10A-01D-A385-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/491ec392-e73d-432a-af03-ddf8cbad35a2

The open-access MAF lists 188 somatic variants for this specimen: 142 protein-altering or splice-affecting, 43 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 116, Silent 43, Nonsense Mutation 10, Splice Site 7, Frame Shift Del 4, Splice Region 3, Intron 2, Translation Start Site 1, 3'UTR 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABL2 | c.3064G>A p.G1022R (on ENST00000502732 / NM_007314.4; = p.G1007R on NM_005158.5) | Missense Mutation (SNP) | VAF 13/69 reads (19%) | SIFT tolerated, low confidence (0.27); PolyPhen possibly damaging (0.779); catalogued as rs1279274624, COSV100772318; called by muse, mutect2, varscan2
- ABO | c.237G>T p.P79= | Splice Region (SNP) | VAF 5/27 reads (19%) | catalogued as COSV101505921, COSV71743426; called by muse, mutect2
- ACOX2 | c.381G>T p.R127S | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT tolerated (0.82); PolyPhen benign (0.007); catalogued as COSV100249955; called by muse, mutect2, varscan2
- ACOXL | c.1541T>C p.L514S (on ENST00000389811 / NM_001371254.1; = p.L484S on NM_001142807.4) | Missense Mutation (SNP) | VAF 6/90 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101093855; called by muse, mutect2
- ACTN2 | c.1498A>G p.R500G | Missense Mutation (SNP) | VAF 20/207 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100856490; called by muse, mutect2
- ACTR3B | c.44+2T>A p.X15_splice | Splice Site (SNP) | VAF 13/39 reads (33%) | catalogued as COSV99753498; called by muse, varscan2
- ADCY3 | c.2894A>T p.N965I | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.158); catalogued as COSV99567526; called by muse, mutect2
- ADGRV1 | c.18736C>T p.Q6246* | Nonsense Mutation (SNP) | VAF 11/114 reads (10%) | catalogued as COSV101315376; called by muse, mutect2
- ANO7 | c.1507G>T p.V503L (on ENST00000274979; = p.V449L on NM_001370694.2) | Missense Mutation (SNP) | VAF 4/66 reads (6%) | SIFT tolerated (0.17); PolyPhen benign (0.009); catalogued as COSV99237135; called by muse, mutect2
- APAF1 | c.271A>G p.I91V | Missense Mutation (SNP) | VAF 31/94 reads (33%) | SIFT tolerated (0.51); PolyPhen benign (0.003); catalogued as rs139951279, COSV100141651; called by muse, mutect2, varscan2
- ARHGAP24 | c.847A>G p.M283V (on ENST00000395184 / NM_001025616.3; = p.M190V on NM_031305.3) | Missense Mutation (SNP) | VAF 23/127 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.366); catalogued as COSV99981753; called by muse, mutect2, varscan2
- ARID4B | c.2429A>G p.D810G | Missense Mutation (SNP) | VAF 5/79 reads (6%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.001); catalogued as rs1450294506, COSV99934844; called by muse, mutect2
- ASXL3 | c.3193C>G p.R1065G | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.997); catalogued as COSV52481019, COSV99322995; called by muse, mutect2, varscan2
- ATF7IP | c.1219G>A p.V407I | Missense Mutation (SNP) | VAF 16/105 reads (15%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0); catalogued as COSV99661101; called by muse, mutect2, varscan2
- ATG9B | c.316A>G p.T106A | Missense Mutation (SNP) | VAF 7/97 reads (7%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); catalogued as rs756173035, COSV99873605; called by muse, mutect2
- AZIN1 | c.250G>C p.G84R | Missense Mutation (SNP) | VAF 12/270 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV100457298; called by muse, mutect2
- BRIP1 | c.2737T>G p.S913A | Missense Mutation (SNP) | VAF 31/174 reads (18%) | SIFT tolerated (0.75); PolyPhen benign (0.026); catalogued as rs1555573382, COSV99369027; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BTNL9 | c.316T>A p.L106M | Missense Mutation (SNP) | VAF 28/144 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.926); catalogued as COSV100576072; called by muse, mutect2, varscan2
- C5orf38 | c.26T>C p.F9S | Missense Mutation (SNP) | VAF 26/139 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as COSV100121546; called by muse, mutect2, varscan2
- CCNA1 | c.328T>C p.S110P | Missense Mutation (SNP) | VAF 18/129 reads (14%) | SIFT tolerated (0.31); PolyPhen benign (0.006); catalogued as COSV99714224; called by muse, mutect2, varscan2
- CDKN2B | c.133C>A p.R45S | Missense Mutation (SNP) | VAF 5/99 reads (5%) | SIFT tolerated (0.53); PolyPhen benign (0.009); catalogued as COSV99439414; called by muse, mutect2
- CEP350 | c.2893G>A p.A965T | Missense Mutation (SNP) | VAF 57/191 reads (30%) | SIFT tolerated (0.15); PolyPhen benign (0.024); catalogued as COSV100854266; called by muse, mutect2, varscan2
- CLCA1 | c.1566G>T p.W522C | Missense Mutation (SNP) | VAF 12/99 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99321846; called by muse, mutect2, varscan2
- CNOT6 | c.300-2A>G p.X100_splice | Splice Site (SNP) | VAF 14/152 reads (9%) | catalogued as COSV99993366; called by muse, mutect2, varscan2
- COG6 | c.695-2A>T p.X232_splice | Splice Site (SNP) | VAF 20/350 reads (6%) | catalogued as COSV100742549; called by muse, mutect2
- COL11A1 | c.4250G>T p.G1417V | Missense Mutation (SNP) | VAF 57/437 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100614710; called by muse, mutect2, varscan2
- COL11A1 | c.2575G>T p.G859W | Missense Mutation (SNP) | VAF 11/132 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100614711; called by muse, mutect2
- CPAMD8 | c.2071T>G p.Y691D (on ENST00000651564; = p.Y644D on NM_015692.5) | Missense Mutation (SNP) | VAF 12/99 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.837); catalogued as COSV99358878; called by muse, mutect2, varscan2
- CPNE3 | c.706C>G p.L236V | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.213); catalogued as COSV99547043; called by muse, mutect2, varscan2
- CPS1 | c.428G>A p.W143* | Nonsense Mutation (SNP) | VAF 9/105 reads (9%) | catalogued as COSV99241833; called by muse, mutect2
- CPS1 | c.3949C>T p.R1317W | Missense Mutation (SNP) | VAF 18/112 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as rs1458915316, COSV51801131, COSV51805896; called by muse, mutect2, varscan2
- CRPPA | c.134A>C p.Q45P | Missense Mutation (SNP) | VAF 61/499 reads (12%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV101235269; called by muse, mutect2, varscan2
- DAZAP1 | c.1183C>T p.Q395* | Nonsense Mutation (SNP) | VAF 11/62 reads (18%) | catalogued as COSV99244933; called by muse, mutect2, varscan2
- DDX17 | c.1123A>T p.T375S | Missense Mutation (SNP) | VAF 10/111 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.044); catalogued as COSV99318536; called by muse, mutect2
- DFFB | c.650T>C p.L217P | Missense Mutation (SNP) | VAF 18/117 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100138596; called by muse, mutect2, varscan2
- DISC1 | c.1127T>C p.L376S | Missense Mutation (SNP) | VAF 24/220 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as COSV99696976; called by muse, mutect2, varscan2
- DISP3 | c.83T>A p.F28Y | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.015); catalogued as COSV99607136; called by muse, mutect2, varscan2
- DNAH8 | c.6633G>T p.W2211C | Missense Mutation (SNP) | VAF 28/134 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100542944, COSV59433572; called by muse, mutect2, varscan2
- DNAJC6 | c.172A>T p.S58C | Missense Mutation (SNP) | VAF 14/88 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); catalogued as COSV99673834; called by muse, mutect2, varscan2
- DSE | c.431C>T p.A144V | Missense Mutation (SNP) | VAF 4/64 reads (6%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.996); catalogued as COSV100528274; called by muse, mutect2
- EFCAB3 | c.75G>A p.R25= | Splice Region (SNP) | VAF 5/71 reads (7%) | catalogued as rs1380004430, COSV100540005; called by muse, mutect2
- EFNB2 | c.926G>A p.G309E | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV99808509; called by muse, mutect2, varscan2
- EPHA2 | c.828C>A p.C276* | Nonsense Mutation (SNP) | VAF 9/50 reads (18%) | catalogued as COSV64452613; called by muse, mutect2, varscan2
- EPHA4 | c.375C>A p.Y125* | Nonsense Mutation (SNP) | VAF 15/95 reads (16%) | catalogued as COSV99915281; called by muse, mutect2, varscan2
- ERBB4 | c.1910C>A p.P637Q | Missense Mutation (SNP) | VAF 11/90 reads (12%) | SIFT tolerated (0.63); PolyPhen benign (0.154); catalogued as COSV99615125; called by muse, mutect2, varscan2
- ERN2 | c.1955G>C p.G652A | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.646); catalogued as COSV55623306, COSV99890411; called by muse, mutect2, varscan2
- FAM13C | c.658G>C p.V220L | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV53244629, COSV99512923; called by muse, mutect2, varscan2
- FBN2 | c.5182G>T p.G1728* | Nonsense Mutation (SNP) | VAF 59/206 reads (29%) | catalogued as COSV99324381; called by muse, mutect2, varscan2
- FBN2 | c.3080G>T p.C1027F | Missense Mutation (SNP) | VAF 17/187 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52516693, COSV99324385; called by muse, mutect2
- FBXL16 | c.1301T>G p.L434R | Missense Mutation (SNP) | VAF 15/108 reads (14%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.542); catalogued as COSV99556229; called by muse, mutect2, varscan2
- FGD4 | c.53G>C p.S18T | Missense Mutation (SNP) | VAF 18/113 reads (16%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.015); catalogued as COSV99846716; called by muse, mutect2, varscan2
- FLG | c.5111C>A p.S1704Y | Missense Mutation (SNP) | VAF 12/78 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100910390, COSV64241733; called by muse, mutect2, varscan2
- FREM2 | c.13G>C p.G5R | Missense Mutation (SNP) | VAF 24/216 reads (11%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.007); catalogued as COSV99746423; called by muse, varscan2
- GINM1 | c.800T>G p.L267W | Missense Mutation (SNP) | VAF 36/163 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV100805268; called by muse, mutect2, varscan2
- GRIA2 | c.1452G>A p.M484I | Missense Mutation (SNP) | VAF 28/156 reads (18%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.542); catalogued as COSV99642691; called by muse, mutect2, varscan2
- HEATR1 | c.1105G>A p.G369R | Missense Mutation (SNP) | VAF 10/84 reads (12%) | SIFT tolerated (0.47); PolyPhen benign (0.05); catalogued as COSV100857335; called by muse, mutect2
- HIPK1 | c.823T>G p.L275V | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV101060165; called by muse, mutect2, varscan2
- HOXA2 | c.70T>A p.S24T | Missense Mutation (SNP) | VAF 61/481 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV99760966; called by muse, mutect2, varscan2
- ICAM5 | c.1775G>C p.R592P | Missense Mutation (SNP) | VAF 13/69 reads (19%) | SIFT tolerated (0.19); PolyPhen benign (0.082); catalogued as COSV99703056; called by muse, mutect2, varscan2
- IFI44L | c.956T>C p.V319A | Missense Mutation (SNP) | VAF 21/82 reads (26%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.957); catalogued as COSV100654848; called by muse, mutect2, varscan2
- IGF1R | c.912G>A p.M304I | Missense Mutation (SNP) | VAF 208/814 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1398752572, COSV51371257; called by muse, mutect2, varscan2
- JADE2 | c.1322A>T p.Q441L | Missense Mutation (SNP) | VAF 33/109 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.09); catalogued as COSV99252627; called by muse, mutect2, varscan2
- JAML | c.774A>G p.T258= (on ENST00000356289 / NM_001098526.2; = p.T248= on NM_153206.3) | Splice Region (SNP) | VAF 11/72 reads (15%) | catalogued as COSV99409217; called by muse, mutect2, varscan2
- KASH5 | c.1387G>C p.V463L | Missense Mutation (SNP) | VAF 5/73 reads (7%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); catalogued as rs900895519, COSV101483378; called by muse, mutect2
- KDR | c.1297G>T p.D433Y | Missense Mutation (SNP) | VAF 17/129 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV55772825, COSV55779397; called by muse, mutect2, varscan2
- KEAP1 | c.1774A>G p.S592G | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT tolerated (0.28); PolyPhen benign (0.082); catalogued as COSV99407225; called by muse, mutect2, varscan2
- KIF25 | c.272A>T p.Q91L | Missense Mutation (SNP) | VAF 16/138 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.005); catalogued as COSV100596224; called by muse, mutect2, varscan2
- LAMA1 | c.8533T>C p.Y2845H | Missense Mutation (SNP) | VAF 15/106 reads (14%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.646); catalogued as COSV101054695; called by mutect2, varscan2
- LAMP5 | c.382A>C p.M128L | Missense Mutation (SNP) | VAF 22/85 reads (26%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV99855409; called by muse, mutect2, varscan2
- LAYN | c.982T>C p.S328P (on ENST00000375615 / NM_001258390.1; = p.S320P on NM_178834.5) | Missense Mutation (SNP) | VAF 31/159 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.023); catalogued as COSV100986138; called by muse, mutect2, varscan2
- LENG9 | c.590G>T p.C197F | Missense Mutation (SNP) | VAF 8/82 reads (10%) | SIFT tolerated (0.7); PolyPhen benign (0.001); catalogued as COSV100002638; called by muse, mutect2
- LRBA | c.5690A>T p.N1897I | Missense Mutation (SNP) | VAF 14/104 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100840837; called by muse, mutect2, varscan2
- LRFN5 | c.116A>T p.K39M | Missense Mutation (SNP) | VAF 20/144 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV99982229; called by muse, mutect2, varscan2
- LRRC71 | c.1215A>C p.E405D | Missense Mutation (SNP) | VAF 57/381 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as COSV100503748; called by muse, mutect2, varscan2
- LRRIQ1 | c.4420A>T p.I1474F | Missense Mutation (SNP) | VAF 13/218 reads (6%) | SIFT tolerated (0.79); PolyPhen benign (0); catalogued as rs202153512, COSV101279310; called by muse, mutect2
- MUC17 | c.13461G>C p.Q4487H | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.027); catalogued as COSV100071334; called by muse, mutect2
- MXD3 | c.598C>T p.H200Y | Missense Mutation (SNP) | VAF 10/97 reads (10%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as rs1165540290, COSV100293411; called by muse, mutect2, varscan2
- NALCN | c.3037G>A p.G1013S | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.974); catalogued as rs773376286, COSV51918505, COSV51963952; called by muse, mutect2, varscan2
- NFE2L3 | c.919C>T p.Q307* | Nonsense Mutation (SNP) | VAF 13/222 reads (6%) | catalogued as COSV99283429; called by muse, mutect2
- NFXL1 | c.671A>G p.K224R | Missense Mutation (SNP) | VAF 16/265 reads (6%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as COSV100216521; called by muse, mutect2
- NMUR2 | c.1051T>A p.S351T | Missense Mutation (SNP) | VAF 16/165 reads (10%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs368060763; called by muse, mutect2, varscan2
- NOX4 | c.458A>T p.K153I | Missense Mutation (SNP) | VAF 33/238 reads (14%) | SIFT tolerated (0.52); PolyPhen benign (0.19); catalogued as COSV54452744, COSV99629345; called by muse, mutect2, varscan2
- NR5A1 | c.119C>T p.T40M | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1564153707, COSV101007629; called by muse, mutect2, varscan2
- NSD1 | c.8002G>A p.G2668R | Missense Mutation (SNP) | VAF 24/241 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.459); catalogued as COSV100728317; called by muse, mutect2
- NSD2 | c.2303A>G p.H768R | Missense Mutation (SNP) | VAF 4/70 reads (6%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.623); catalogued as rs959360615, COSV100372756; called by muse, mutect2
- NVL | c.1244C>T p.S415L | Missense Mutation (SNP) | VAF 5/70 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); catalogued as COSV55871386; called by muse, mutect2
- OPA3 | c.204C>G p.I68M | Missense Mutation (SNP) | VAF 14/218 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.778); catalogued as COSV99840793; called by muse, mutect2
- OR2T6 | c.8A>G p.E3G | Missense Mutation (SNP) | VAF 6/96 reads (6%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs1448610730, COSV100861468; called by muse, mutect2
- OR51G1 | c.680T>C p.V227A | Missense Mutation (SNP) | VAF 19/87 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.874); catalogued as COSV100429097; called by muse, mutect2, varscan2
- OTOP1 | c.1352C>T p.P451L | Missense Mutation (SNP) | VAF 14/109 reads (13%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.704); catalogued as rs951883306, COSV99587285; called by muse, mutect2, varscan2
- PANK4 | c.1975G>A p.D659N | Missense Mutation (SNP) | VAF 20/108 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99615360; called by muse, varscan2
- PAX3 | c.1250G>C p.G417A | Missense Mutation (SNP) | VAF 12/115 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.724); catalogued as COSV100398904, COSV100399936; called by muse, mutect2, varscan2
- PCDHA5 | c.1688C>T p.A563V | Missense Mutation (SNP) | VAF 24/84 reads (29%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.005); catalogued as COSV65358823; called by muse, mutect2, varscan2
- PCDHB4 | c.407A>T p.E136V | Missense Mutation (SNP) | VAF 49/150 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.59); catalogued as COSV99521791; called by muse, mutect2, varscan2
- PDCD2L | c.976G>A p.V326I | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT tolerated (0.55); PolyPhen benign (0.06); catalogued as COSV99874841; called by muse, mutect2, varscan2
- PDZK1 | c.379G>A p.V127M | Missense Mutation (SNP) | VAF 106/315 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0.396); catalogued as rs1553701782, COSV100777340; called by muse, mutect2, varscan2
- PGAP1 | c.525G>C p.M175I | Missense Mutation (SNP) | VAF 28/134 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as COSV100697953; called by muse, mutect2, varscan2
- PHF11 | c.577G>A p.E193K | Missense Mutation (SNP) | VAF 17/222 reads (8%) | SIFT tolerated (0.54); PolyPhen benign (0.003); catalogued as rs368988100, COSV100710505; called by muse, mutect2
- PI4KA | c.3386C>T p.P1129L | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99743956; called by muse, mutect2, varscan2
- PKD1 | c.3980A>C p.D1327A | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.61); catalogued as COSV99237002; called by muse, mutect2, varscan2
- PLB1 | c.1206+2T>G p.X402_splice | Splice Site (SNP) | VAF 13/95 reads (14%) | catalogued as COSV100214703; called by muse, mutect2, varscan2
- PLEKHB2 | c.121C>T p.Q41* | Nonsense Mutation (SNP) | VAF 7/59 reads (12%) | catalogued as rs868315486, COSV99301486; called by muse, mutect2, varscan2
- POLG | c.1996C>T p.Q666* | Nonsense Mutation (SNP) | VAF 12/31 reads (39%) | catalogued as rs1361580021, COSV99174456; called by muse, mutect2, varscan2
- PPAT | c.209T>C p.V70A | Missense Mutation (SNP) | VAF 5/55 reads (9%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.755); catalogued as COSV99946998; called by muse, mutect2, varscan2
- PPP2R1A | c.749A>T p.Q250L | Missense Mutation (SNP) | VAF 23/47 reads (49%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV100435993; called by muse, mutect2, varscan2
- PRDM13 | c.298G>A p.D100N | Missense Mutation (SNP) | VAF 17/113 reads (15%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.922); catalogued as COSV100980429; called by muse, mutect2, varscan2
- PRPF38A | c.250A>T p.K84* | Nonsense Mutation (SNP) | VAF 8/105 reads (8%) | catalogued as COSV99933128; called by muse, mutect2
- PRSS16 | c.365G>T p.W122L | Missense Mutation (SNP) | VAF 3/36 reads (8%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as COSV100041493, COSV57916756; called by muse, mutect2
- PSG11 | c.686A>G p.D229G | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.868); catalogued as COSV100105413; called by muse, mutect2
- RAD50 | c.3292C>T p.R1098W | Missense Mutation (SNP) | VAF 40/336 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.654); catalogued as rs750947088, COSV54750064; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RALGPS2 | c.1598C>A p.P533H | Missense Mutation (SNP) | VAF 8/84 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.954); catalogued as COSV100860595; called by muse, mutect2
- SI | c.2750C>A p.A917E | Missense Mutation (SNP) | VAF 16/148 reads (11%) | SIFT tolerated (0.25); PolyPhen benign (0.001); catalogued as COSV100013613; called by muse, varscan2
- SLC14A2 | c.1908-1G>C p.X636_splice | Splice Site (SNP) | VAF 14/62 reads (23%) | catalogued as COSV54911550, COSV99674911; called by muse, mutect2, varscan2
- SLC35E3 | c.514T>C p.W172R | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100097947; called by muse, mutect2, varscan2
- SLC7A10 | c.469C>A p.P157T | Missense Mutation (SNP) | VAF 9/109 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs776698377, COSV53502946, COSV99471919; called by muse, mutect2
- SNAP91 | c.2590A>G p.M864V | Missense Mutation (SNP) | VAF 33/243 reads (14%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.448); catalogued as rs1417622047, COSV99534101; called by muse, mutect2, varscan2
- SNURF | c.208G>C p.G70R | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT tolerated, low confidence (0.08); PolyPhen probably damaging (0.995); catalogued as COSV100577815; called by muse, mutect2, varscan2
- SPATA31D1 | c.1373T>C p.I458T | Missense Mutation (SNP) | VAF 22/175 reads (13%) | SIFT tolerated (0.37); PolyPhen benign (0.07); catalogued as rs201640408; called by muse, mutect2, varscan2
- SPTAN1 | c.923A>G p.E308G | Missense Mutation (SNP) | VAF 10/99 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.006); catalogued as COSV100823189; called by muse, mutect2
- SUSD2 | c.1891+1G>C p.X631_splice | Splice Site (SNP) | VAF 5/33 reads (15%) | catalogued as COSV100844134; called by muse, mutect2, varscan2
- TAF1 | c.3428G>A p.R1143H (on ENST00000373790 / NM_138923.4; = p.R1164H on NM_004606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 37/163 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as COSV52122269; called by muse, mutect2, varscan2
- TARBP2 | c.174C>A p.H58Q (on ENST00000266987 / NM_134323.2; = p.H37Q on NM_004178.4) | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV99908352; called by muse, mutect2, varscan2
- TBC1D9 | c.1550C>T p.P517L | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs769634349, COSV71306958; called by muse, mutect2, varscan2
- TENM1 | c.5405A>T p.D1802V | Missense Mutation (SNP) | VAF 28/63 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.643); catalogued as COSV100948863; called by muse, mutect2, varscan2
- TOGARAM1 | c.4486G>T p.G1496C | Missense Mutation (SNP) | VAF 9/88 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); catalogued as COSV100817733; called by muse, mutect2
- TRIOBP | c.3116C>G p.P1039R | Missense Mutation (SNP) | VAF 21/104 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.923); catalogued as COSV100730532; called by muse, mutect2, varscan2
- TSC1 | c.2024A>G p.D675G | Missense Mutation (SNP) | VAF 10/102 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.984); catalogued as COSV100050953; called by muse, mutect2
- VEGFC | c.938A>G p.N313S | Missense Mutation (SNP) | VAF 7/76 reads (9%) | SIFT tolerated (0.3); PolyPhen benign (0.089); catalogued as COSV99709330; called by muse, mutect2
- VWA8 | c.3995C>T p.P1332L | Missense Mutation (SNP) | VAF 5/62 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.176); catalogued as COSV101022275; called by muse, mutect2
- XPO1 | c.455A>T p.D152V | Missense Mutation (SNP) | VAF 38/229 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV101294138; called by muse, mutect2, varscan2
- ZNF577 | c.1390A>G p.N464D | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.739); catalogued as COSV100030684; called by muse, mutect2, varscan2
- ZNF611 | c.106G>T p.A36S | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.035); catalogued as COSV100159943; called by muse, mutect2, varscan2
- ADAMTS2 | c.2607del p.C870Vfs*120 | Frame Shift Del (DEL) | VAF 9/41 reads (22%) | called by mutect2, pindel, varscan2
- BAP1 | c.1984-18_1997del p.X662_splice | Splice Site (DEL) | VAF 22/81 reads (27%) | called by mutect2, pindel, varscan2
- DKK2 | c.307_329del p.C103Pfs*14 | Frame Shift Del (DEL) | VAF 14/84 reads (17%) | called by mutect2, pindel, varscan2
- GPR179 | c.1562C>A p.A521E (on ENST00000621958; = p.A520E on NM_001004334.4) | Missense Mutation (SNP) | VAF 24/149 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.139); called by muse, mutect2, varscan2
- IDH2 | c.1098dup p.N367Qfs*113 | Frame Shift Ins (INS) | VAF 10/43 reads (23%) | called by mutect2, pindel, varscan2
- KIAA1549 | c.1334G>A p.G445E | Missense Mutation (SNP) | VAF 13/91 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); called by muse, mutect2, varscan2
- LRCH3 | c.1A>C p.M1? | Translation Start Site (SNP) | VAF 24/106 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.138); called by muse, varscan2
- PRAMEF18 | c.694A>T p.R232W | Missense Mutation (SNP) | VAF 72/1202 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.717); called by muse, mutect2
- PTPRCAP | c.41_51del p.A14Gfs*43 | Frame Shift Del (DEL) | VAF 6/47 reads (13%) | called by mutect2, pindel, varscan2
- SCN7A | c.3800_3801del p.A1267Dfs*6 | Frame Shift Del (DEL) | VAF 24/180 reads (13%) | called by mutect2, pindel*, varscan2*
- ADAM29 | c.1110T>C p.S370= | Silent (SNP) | VAF 23/104 reads (22%) | catalogued as COSV100821880; called by muse, mutect2, varscan2
- AHCTF1 | c.4530G>A p.E1510= (on ENST00000366508; = p.E1484= on NM_015446.5) | Silent (SNP) | VAF 37/343 reads (11%) | catalogued as rs896943331, COSV100403014; called by muse, mutect2, varscan2
- AMY2A | c.393A>T p.G131= | Silent (SNP) | VAF 39/244 reads (16%) | catalogued as COSV101340613; called by muse, mutect2, varscan2
- ANK3 | c.3537C>A p.L1179= (on ENST00000280772 / NM_001320874.2; = p.L313= on NM_001149.3) | Silent (SNP) | VAF 8/58 reads (14%) | catalogued as COSV99777929; called by muse, mutect2, varscan2
- ARHGAP11B | c.378G>A p.R126= | Silent (SNP) | VAF 24/362 reads (7%) | catalogued as COSV101451758; called by muse, mutect2
- ASTN1 | c.1431C>T p.P477= | Silent (SNP) | VAF 14/163 reads (9%) | catalogued as rs773583241, COSV99920184; called by muse, mutect2
- BNC1 | c.363A>G p.Q121= | Silent (SNP) | VAF 12/100 reads (12%) | catalogued as COSV100596851, COSV100597605; called by muse, mutect2, varscan2
- CNTN6 | c.2895A>G p.P965= | Silent (SNP) | VAF 27/223 reads (12%) | catalogued as rs773206932, COSV100609919; called by muse, mutect2, varscan2
- COL12A1 | c.171A>T p.I57= | Silent (SNP) | VAF 15/92 reads (16%) | catalogued as COSV100485242; called by muse, mutect2, varscan2
- CPNE5 | c.1572C>T p.P524= | Silent (SNP) | VAF 6/31 reads (19%) | catalogued as rs1037358771, COSV99782351; called by muse, mutect2, varscan2
- DNAH3 | c.1180C>T p.L394= | Silent (SNP) | VAF 14/65 reads (22%) | catalogued as COSV99764568; called by muse, mutect2, varscan2
- DNAJC11 | c.1314G>A p.A438= | Silent (SNP) | VAF 3/22 reads (14%) | catalogued as rs748237613; called by mutect2, varscan2
- DZIP1L | c.2133G>A p.R711= | Silent (SNP) | VAF 41/112 reads (37%) | catalogued as COSV100551052; called by muse, mutect2, varscan2
- EGFLAM | c.2125T>C p.L709= | Silent (SNP) | VAF 10/129 reads (8%) | catalogued as COSV100379683; called by muse, mutect2
- ESPN | c.321C>T p.V107= | Silent (SNP) | VAF 23/99 reads (23%) | catalogued as COSV100911323; called by muse, mutect2, varscan2
- EXOC3L2 | c.1839C>T p.Y613= | Silent (SNP) | VAF 10/92 reads (11%) | catalogued as COSV99374431; called by muse, mutect2, varscan2
- FABP4 | c.393A>G p.R131= | Silent (SNP) | VAF 14/100 reads (14%) | catalogued as rs756886921, COSV99808460; called by muse, mutect2, varscan2
- FAM81B | c.478C>T p.L160= | Silent (SNP) | VAF 7/140 reads (5%) | catalogued as COSV99352458; called by muse, mutect2
- FLT4 | c.1671C>T p.G557= | Silent (SNP) | VAF 11/73 reads (15%) | catalogued as COSV99985736; called by muse, mutect2, varscan2
- HCAR2 | c.495G>A p.K165= | Silent (SNP) | VAF 7/79 reads (9%) | catalogued as COSV61024061; called by muse, mutect2
- ICAM5 | c.1155C>T p.A385= | Silent (SNP) | VAF 14/90 reads (16%) | catalogued as COSV99703054; called by muse, mutect2, varscan2
- IFT57 | c.1254C>T p.A418= | Silent (SNP) | VAF 19/104 reads (18%) | catalogued as rs1317938805, COSV99197182; called by muse, mutect2, varscan2
- IQGAP1 | c.876G>A p.T292= | Silent (SNP) | VAF 49/226 reads (22%) | catalogued as rs375134287; called by muse, mutect2, varscan2
- KCNC2 | c.153C>T p.G51= | Silent (SNP) | VAF 9/44 reads (20%) | catalogued as COSV100128103; called by muse, mutect2, varscan2
- KCNG3 | c.861C>G p.T287= | Silent (SNP) | VAF 18/126 reads (14%) | catalogued as COSV100044713; called by muse, mutect2, varscan2
- LRRC37A3 | c.2238T>C p.T746= | Silent (SNP) | VAF 31/307 reads (10%) | catalogued as rs771513010, COSV100140785; called by muse, mutect2, varscan2
- MTHFR | c.264C>G p.P88= | Silent (SNP) | VAF 28/84 reads (33%) | catalogued as COSV100411493; called by muse, mutect2, varscan2
- OLFML2A | c.1278C>T p.D426= | Silent (SNP) | VAF 10/81 reads (12%) | catalogued as rs756535506, COSV99992327; called by muse, mutect2, varscan2
- OR2T8 | c.648T>C p.Y216= | Silent (SNP) | VAF 19/268 reads (7%) | called by muse, mutect2
- PDE1C | c.372G>A p.K124= | Silent (SNP) | VAF 10/61 reads (16%) | catalogued as COSV100370614, COSV58515279; called by muse, mutect2, varscan2
- PFAS | c.2064G>T p.V688= | Silent (SNP) | VAF 11/98 reads (11%) | catalogued as COSV100118719; called by muse, mutect2
- PGK1 | c.36G>A p.L12= | Silent (SNP) | VAF 21/38 reads (55%) | catalogued as COSV100965283; called by muse, mutect2, varscan2
- PPP5C | c.1473C>T p.N491= | Silent (SNP) | VAF 27/102 reads (26%) | catalogued as COSV99180821; called by muse, mutect2, varscan2
- RPE65 | c.327A>G p.P109= | Silent (SNP) | VAF 20/103 reads (19%) | catalogued as rs1356737522, COSV52019537; called by muse, mutect2, varscan2
- SELENOO | c.1464G>A p.E488= | Silent (SNP) | VAF 8/41 reads (20%) | catalogued as rs780435148, COSV99954701; called by muse, mutect2, varscan2
- SERPINB7 | c.297G>C p.V99= | Silent (SNP) | VAF 11/88 reads (13%) | catalogued as COSV100320359; called by muse, mutect2, varscan2
- SLC5A8 | c.1005A>G p.P335= | Silent (SNP) | VAF 16/200 reads (8%) | catalogued as rs367557492; called by muse, mutect2
- TTN | c.85152G>A p.V28384= (on ENST00000591111; = p.V20960= on NM_003319.4) | Silent (SNP) | VAF 12/172 reads (7%) | catalogued as rs1161233801, COSV100591393; ClinVar: likely benign; called by muse, mutect2
- XAF1 | c.264C>T p.F88= | Silent (SNP) | VAF 15/136 reads (11%) | catalogued as COSV100694953; called by muse, mutect2, varscan2
- ZNF300 | c.813T>C p.C271= | Silent (SNP) | VAF 26/104 reads (25%) | catalogued as COSV99199785; called by muse, mutect2, varscan2
- ZNF677 | c.1179T>C p.H393= | Silent (SNP) | VAF 11/108 reads (10%) | catalogued as COSV100447754; called by muse, mutect2, varscan2
- ZNF766 | c.780A>C p.R260= | Silent (SNP) | VAF 25/106 reads (24%) | catalogued as COSV100765243; called by muse, mutect2, varscan2
- ZNF831 | c.3636T>C p.P1212= | Silent (SNP) | VAF 22/100 reads (22%) | catalogued as COSV100925733; called by muse, mutect2, varscan2
- NAP1L4 | c.*1T>C | 3'UTR (SNP) | VAF 152/451 reads (34%) | catalogued as COSV101000634; called by muse, mutect2, varscan2
- TTN | c.34264+5300G>A | Intron (SNP) | VAF 6/68 reads (9%) | catalogued as rs1212119650, COSV100591395; called by muse, mutect2
- TTN | c.34264+3386C>T | Intron (SNP) | VAF 13/78 reads (17%) | catalogued as rs757640925, COSV100591396; called by muse, mutect2, varscan2
